Gene-level copy-number profile of tumor specimen TCGA-DA-A1HW-06A from TCGA case TCGA-DA-A1HW, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 37.2 years (13,592 days).
Specimen TCGA-DA-A1HW-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.c11aaeed-d25d-4fe9-a7a8-35b51eabec0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DA-A1HW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8aee7596-0e1e-4c0e-87aa-8e4f2c339073

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 243; copy number 2: 20,763; copy number 3: 4,676; copy number 4: 31,488; copy number 5: 566; copy number 6: 1,540; copy number 7: 170; copy number 8: 95; copy number 9: 114; copy number 10: 151.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DA-A1HW-06A-11D-A192-01): tumor purity 0.67, ploidy 1.63, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,523,001, 4 genes: LINC00290, AC019235.1, LINC02500, AC093840.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 265 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:69,739,464–75,435,110, 80 genes, copy number 10 (broad region; genes not listed).
- chr3:75,446,769–75,491,202, 1 gene, copy number 10 (within-gene range 6–10): ENPP7P2.
- chr3:107,377,439–110,529,582, 43 genes, copy number 10: CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1.
- chr7:5,620,047–5,781,696, 1 gene, copy number 9 (within-gene range 3–9): RNF216.
- chr7:5,711,840–7,535,873, 55 genes, copy number 9 (within-gene range 5–9): MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2, CCZ1B, OR7E39P, UNC93B2, OR7E136P, OR7E59P, AC079804.2, ALG1L5P, AC079804.1, FAM86LP, AC079804.3, MIR3683, AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1.
- chr11:34,853,094–36,289,449, 27 genes, copy number 10: APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9.
- chr15:90,001,324–91,022,566, 53 genes, copy number 9 (within-gene range 5–9): ZNF710, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1, CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585, BLM, SNORD18, AC124248.2, AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3, UNC45A, RCCD1-AS1, RCCD1, PRC1, AC068831.6, PRC1-AS1, Y_RNA.
- chr15:91,853,708–92,331,037, 5 genes, copy number 9 (within-gene range 5–9): SLCO3A1, AC116903.2, AC116903.1, DUXAP6, NPM1P5.

Autosomal genes at a single copy (total copy number 1): 243. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
